Surgical pathology report (de-identified scan), TCGA case TCGA-F1-A448, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site UNC, specimen TCGA-F1-A448-01A (Primary Tumor).

[page 1 of 5]
SURGICAL PATHOLOGY REVISED REPORT

Case Number :

Diagnosis:

A: Distal stomach, proximal duodenum, and perigastric lymph nodes, resection

Tumor histologic type/subtype: mucinous adenocarcinoma with focal areas of diffuse pattern and signet ring cell pattern (see comment)

Histologic grade: grade 3 of 4 (poorly differentiated)

Tumor size: 9.3 cm (at least)

Tumor location: stomach, lesser curvature

Depth of invasion: through muscularis propria and into lesser curvature perigastric fibroadipose tissue

Lymphovascular invasion: present

Perineural invasion: not identified

Histologic assessment of surgical margins:

Proximal margin: negative, 3.2 cm away

Distal margin: negative, 5.7 cm away

Radial margin: negative

Lymph nodes: metastatic adenocarcinoma present in 16 of 42 perigastric lymph nodes attached to this specimen (see specimens B, C, D, and E for separately submitted lymph nodes)

Size of largest nodal metastasis: 1.55 cm

Extranodal extension: present

Other significant findings: background chronic atrophic gastritis

AJCC Staging: pT3 pN3b

This staging information is based on this pathologic specimen

Joint Synchronous Primary Notes		X
Pathologic Complete Response		

[page 2 of 5]
and may be incomplete. A comprehensive review of all available information is recommended to determine final staging.

B: Omentum, omentectomy

- No metastatic adenocarcinoma identified within omental fibroadipose tissue or 3 lymph nodes (0/3)

C: Lymph nodes, left gastric, biopsy

- No metastatic adenocarcinoma identified
- No lymph nodes identified
- Entire specimen submitted for microscopic examination

D: Lymph nodes, celiac, dissection

- Metastatic adenocarcinoma present in 1 of 11 lymph nodes (1/11)

E: Lymph nodes, splenic artery, biopsy

- Metastatic adenocarcinoma present in 1 of 5 lymph nodes (1/5)

F: Additional proximal gastric margin, excision

- Focal intestinal metaplasia
- No dysplasia or adenocarcinoma identified

Comment:

The frozen section diagnoses for specimen A are confirmed.

H & E stained sections show a prominent lymphoid infiltrate surrounding some regions of the tumor. An EBV in situ hybridization stain is negative within the malignant cells.

A HER2/neu immunostain is pending. The result will be issued as an addendum.

Intraoperative Consult Diagnosis:

Frozen sections were requested by

FSA1: Stomach, distal margin, biopsy

- No tumor seen

FSA2: Stomach, proximal margin, biopsy

- No tumor seen

Frozen Section Pathologist:

[page 3 of 5]
Clinical History:

-year-old with gastric cancer.

Gross Description:

Received are six appropriately labeled containers.

Container A is additionally labeled "distal stomach and perigastric lymph nodes." The specimen is received fresh for frozen section and consists of distal stomach with approximately 1 cm of proximal duodenum and associated perigastric fibroadipose tissue. The specimen measures 15 x 11 x 3 cm (lesser curve length - 8.5 cm; greater curve length - 19 cm). The distal margin is inked blue and taken entirely en face in block FSA1. The proximal margin closest to the tumor is taken en face in FSA2 (yellow ink where sampled).

The tumor is a 9.3 x 6 cm protruding mass centered on the lesser curvature occupying approximately 75% of the stomach circumference. It is located 3.2 cm from the proximal gastric margin (as measured at the time of frozen section in the fresh specimen) and 5.7 cm from the duodenal margin. The subserosal fibroadipose tissue is indurated and fixed to the tumor. On cut section the tumor is solid white/tan and invades through the muscularis propria into the lesser omentum fat. Where not covered with fat, the serosal surface is smooth without areas of retraction or puckering, and grossly does not appear to be involved (inked green). Tumor surface has a shallow ulceration, and tumor thickness ranges 1.2 to 1.6 cm. Approximately 40% of the tumor circumference has a rolled, heaped up mucosal border that is next to the ulceration. The rest of the tumor is polypoid without a rolled border, with a well-circumscribed invasive front along the peripheral edge (consistent with Borrmann mixed type 1 and 2). The remainder of the stomach mucosa is pink/tan, granular and appropriately folded. No other lesions are noted. Lymph nodes range in size from 0.2 to 1.6 cm and are submitted per block summary. Areas of matted large veins are not detected.

Tumor and normal tissue are submitted to :

Block summary:

FSA1, FSA2 - frozen section remnants

A3 - gastrointestinal vascular margin

A4 - one 1.5 cm lymph node from lesser curve, bisected

A5 - one lymph node candidate from lesser curve, bisected

A6, A7 - 75% of the remaining proximal margin submitted en face

[page 4 of 5]
A8,A9 - tumor center, deepest invasion (serosal surface inked green)
A10 - proximal edge of tumor
A11 - distal edge of tumor
A12 - edge of tumor in anterior corpus (transition from bare serosal surface to subserosal fat)
A13-A15 - representative sections of tumor
A16-A17 - one lymph node candidate, bisected
A18 - representative pylorus
A19 - representative stomach, 1 cm from tumor
A20 - representative stomach, 3 cm from tumor
A21,A22 - sections of tumor edge without rolled mucosal border
A23 - one lymph node candidate, bisected, lesser curve
A24 - two lymph node candidates, lesser curve
A25 - multiple lymph node candidates, lesser curve
A26 - one lymph node candidate, bisected, lesser curve
A27 - multiple lymph node candidates, lesser curve
A28,A29 - multiple lymph nodes, each cassette, lesser curve
A30,A31 - cluster of at least three lymph nodes, bisected together, and additional fragments of fibroadipose tissue, lesser curve
A32 - one lymph node, fragmented, lesser curve
A33 - representative remaining lesser curve fibroadipose tissue
A34 - one lymph node, bisected, greater curve
A35 - multiple lymph nodes, greater curve
A36 - one lymph node, bisected, greater curve
A37 - one lymph node, bisected, greater curve
A38 - one lymph node, bisected, greater curve
A39,A40 - multiple lymph node candidates, each cassette, greater curve
A41 - representative remaining greater curve fibroadipose tissue

Container B is additionally labeled "omentum." It consists of a 58.0 x 16.5 x 2.5 cm collection of yellow/tan omental tissue. One surface has cautery artifact. The opposite side is yellow/tan and glistening. Serial sections reveal unremarkable yellow lobulated cut surfaces. No firm areas are identified. Representative sections are submitted in blocks B1-B3. Block B4 holds omental lymph node candidate, bisected.

Container C is additionally labeled "left gastric lymph node." It consists of a 5.1 x 4.1 x 0.5 cm fragment of tan/yellow fibrofatty tissue. No lymph nodes are palpated. The specimen is submitted in blocks C1-C3,

Container D is additionally labeled "celiac lymph node." It consists of a 4.5 x 3.7 x 2.5 cm fragment of yellow/tan

[page 5 of 5]
fibrofatty tissue. Multiple lymph node candidates are submitted in blocks D1-D5. Fat remains in formalin.

Container E is additionally labeled "splenic artery lymph nodes." It consists of a 3.5 x 3.1 x 1.5 cm fragmented yellow/tan fibrofatty tissue. Two lymph nodes are identified and submitted in block E1. The remaining fibrofatty tissue is submitted in blocks E2-E4,

Container F is additionally labeled "additional proximal gastric margin." It consists of an 8.5 cm long x 2.0 cm diameter triangular shaped segment of stomach. The specimen is stapled on two sides with an attached 5.5 x 4.3 x 1.3 cm of yellow/tan fibrofatty tissue. The serosal surface of the stomach is gray/tan, smooth and intact. The mucosa is tan/white with normal rugae and a thin layer of dark brown viscous material adherent to it. The gastric wall is 0.2 cm thick throughout. The margins are submitted in blocks F1-F4, en face. No nodes are palpated. Tissue remains in formalin.

Source: NCI Genomic Data Commons file 215d6764-1b40-45d9-98a6-896ff8c54b0a (TCGA-F1-A448.061E27C3-B7C0-45B9-B3AA-A4FB9D41999D.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).